Somatic mutation profile of tumor specimen TCGA-44-6147-01A (aliquot TCGA-44-6147-01A-31D-A27T-08) from TCGA case TCGA-44-6147, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 67.4 years (24,631 days).
Specimen TCGA-44-6147-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 455d27a7-9bca-4f47-86ce-38afccfe9ab5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-44-6147-10A (Blood Derived Normal), aliquot TCGA-44-6147-10A-01D-1753-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8416388e-8a30-441d-b14b-bfcec4daf78a

The open-access MAF lists 128 somatic variants for this specimen: 86 protein-altering or splice-affecting, 42 silent.
By variant classification: Missense Mutation 76, Silent 42, Nonsense Mutation 4, Frame Shift Del 3, Frame Shift Ins 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2303G>T p.S768I | Missense Mutation (SNP) | VAF 18/160 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913465, COSV51768106, COSV51821681, COSV51833841; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- TP53 | c.329G>T p.R110L | Missense Mutation (SNP) | VAF 8/84 reads (10%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.343); catalogued as rs11540654, CM115383, CM134053, CM984590, COSV52662399, COSV52668419, COSV52680444, COSV53132492; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACSM2B | c.1671A>C p.K557N | Missense Mutation (SNP) | VAF 30/362 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61660186; called by muse, mutect2
- ADGRB3 | c.3152A>G p.D1051G | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99484022; called by muse, mutect2
- ADGRF2 | c.616T>A p.W206R (on ENST00000296862 / NM_001368115.2; = p.W138R on NM_153839.7) | Missense Mutation (SNP) | VAF 13/152 reads (9%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV57292367; called by muse, mutect2
- ADGRG2 | c.982C>A p.P328T (on ENST00000379869 / NM_001079858.3; = p.P325T on NM_005756.4) | Missense Mutation (SNP) | VAF 10/208 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as COSV61341592; called by muse, mutect2
- ALMS1 | c.2445G>T p.E815D | Missense Mutation (SNP) | VAF 18/214 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.106); catalogued as COSV100041528; called by muse, mutect2
- ANK1 | c.1667T>A p.L556Q | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55897090; called by muse, mutect2
- ATRX | c.5257A>G p.N1753D | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64884374; called by muse, mutect2, varscan2
- CACNA1E | c.5494G>T p.D1832Y | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62429521; called by muse, mutect2
- CCDC73 | c.1835A>G p.E612G | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.04); catalogued as COSV58805356; called by muse, mutect2, varscan2
- CD101 | c.1473G>T p.W491C | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.961); catalogued as COSV99869248; called by muse, mutect2
- CD101 | c.1474G>T p.A492S | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.715); catalogued as COSV99869256; called by muse, mutect2
- CDH6 | c.709C>A p.Q237K | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.829); catalogued as COSV54068746; called by muse, mutect2, varscan2
- CDHR2 | c.2042T>A p.V681D | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56145998; called by muse, mutect2, varscan2
- COL23A1 | c.436T>C p.Y146H | Missense Mutation (SNP) | VAF 22/280 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV66799365; called by muse, mutect2
- CPA4 | c.277G>T p.D93Y | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV55985261; called by muse, mutect2
- CSF2RB | c.1220G>T p.R407M | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as rs1342778985, COSV53261278; called by muse, mutect2
- CSMD3 | c.7846G>T p.G2616W (on ENST00000297405 / NM_001363185.1; = p.G2512W on NM_052900.3) | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52331340; called by muse, mutect2, varscan2
- CTNNA1 | c.128A>T p.N43I | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.562); catalogued as COSV57081955; called by muse, mutect2
- CTTNBP2 | c.2961T>G p.D987E | Missense Mutation (SNP) | VAF 7/126 reads (6%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV50484331; called by muse, mutect2
- CYTH1 | c.34C>A p.L12M | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV63123819; called by muse, mutect2
- DCLK1 | c.1774G>T p.D592Y | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV55213373; called by muse, mutect2, varscan2
- DCLK3 | c.401G>T p.G134V | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.942); catalogued as COSV69364876; called by muse, mutect2
- EGFR | c.2305G>T p.V769L | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.572); catalogued as rs147149347, COSV51802272, COSV51811749; ClinVar: uncertain significance; called by muse, mutect2
- EPDR1 | c.470C>G p.A157G | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.259); catalogued as COSV52258762, COSV52262160; called by muse, mutect2, varscan2
- ESX1 | c.688G>A p.D230N | Missense Mutation (SNP) | VAF 13/266 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.127); catalogued as COSV65425269; called by muse, mutect2
- EXOC4 | c.2117A>T p.D706V | Missense Mutation (SNP) | VAF 14/149 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.106); catalogued as COSV54124828; called by muse, mutect2
- FAM83B | c.1485G>T p.W495C | Missense Mutation (SNP) | VAF 7/154 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.817); catalogued as COSV60927347; called by muse, mutect2
- FFAR1 | c.443G>A p.G148E | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.114); catalogued as COSV99322956; called by muse, mutect2
- FLG | c.7423G>T p.G2475* | Nonsense Mutation (SNP) | VAF 109/810 reads (13%) | catalogued as COSV64250568; called by muse, mutect2, varscan2
- FOXL1 | c.1029C>A p.H343Q | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV100206133; called by muse, mutect2, varscan2
- FSCB | c.2296G>T p.A766S | Missense Mutation (SNP) | VAF 30/149 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.494); catalogued as rs1246242313, COSV100468972; called by muse, mutect2, varscan2
- GRM1 | c.1329G>T p.K443N | Missense Mutation (SNP) | VAF 7/158 reads (4%) | SIFT tolerated (0.32); PolyPhen benign (0.434); catalogued as COSV99264716; called by muse, mutect2
- H6PD | c.1124A>T p.N375I | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as COSV66232499; called by muse, mutect2
- HMCN1 | c.13693delinsTT p.G4565Lfs*17 | Frame Shift Ins (INS) | VAF 13/58 reads (22%) | catalogued as COSV99623534; called by mutect2*, pindel, varscan2*
- IGKV3-11 | c.304G>T p.D102Y | Missense Mutation (SNP) | VAF 20/192 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758486991; called by muse, mutect2, varscan2
- ITIH6 | c.2668C>A p.P890T | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.093); catalogued as COSV54495150; called by muse, mutect2, varscan2
- KCNJ6 | c.223C>A p.R75S | Missense Mutation (SNP) | VAF 20/206 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55713174, COSV55724009; called by muse, mutect2
- KCTD19 | c.1465G>A p.E489K | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.024); catalogued as COSV58575473; called by muse, mutect2, varscan2
- KRTAP10-3 | c.112G>T p.A38S | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV100552310, COSV59959098; called by muse, mutect2
- LAMB4 | c.3890C>A p.S1297Y | Missense Mutation (SNP) | VAF 20/222 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.072); catalogued as COSV52732020; called by muse, mutect2
- MAP2 | c.829G>T p.E277* | Nonsense Mutation (SNP) | VAF 6/84 reads (7%) | catalogued as COSV52309380; called by muse, mutect2
- MGAM | c.1230G>T p.Q410H | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72075973; called by muse, mutect2
- MSH4 | c.1723A>G p.I575V | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.068); catalogued as COSV54213468; called by muse, mutect2, varscan2
- MTMR14 | c.1007G>T p.R336L | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as CM065043, COSV56004553, COSV56007889; called by muse, mutect2
- MUC17 | c.11840C>A p.T3947N | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.432); catalogued as rs1454428134, COSV60305354; called by muse, mutect2, varscan2
- MYO7B | c.1941C>A p.C647* | Nonsense Mutation (SNP) | VAF 5/51 reads (10%) | catalogued as COSV101267952; called by muse, mutect2, varscan2
- OPRL1 | c.654C>A p.C218* | Nonsense Mutation (SNP) | VAF 16/121 reads (13%) | catalogued as rs767233709, COSV61093080; called by muse, mutect2, varscan2
- OR2M4 | c.605G>A p.C202Y | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV60709843; called by muse, mutect2, varscan2
- OR5T2 | c.236T>G p.M79R | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as COSV57591116; called by muse, mutect2
- PCDH11X | c.338C>A p.A113D | Missense Mutation (SNP) | VAF 20/172 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV53508284; called by muse, mutect2, varscan2
- PFKP | c.420G>T p.E140D | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV101127029; called by muse, mutect2
- PHF20 | c.2232G>C p.Q744H | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.993); catalogued as COSV64978119; called by muse, mutect2, varscan2
- PLPPR4 | c.1024G>T p.D342Y | Missense Mutation (SNP) | VAF 8/159 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV64567841; called by muse, mutect2
- PPM1D | c.418G>T p.A140S | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0.246); catalogued as COSV59958225; called by muse, mutect2, varscan2
- PRRC2C | c.4617A>T p.E1539D (on ENST00000367742; = p.E1537D on NM_015172.4) | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV58914159; called by muse, mutect2
- PTPRN2 | c.1216C>T p.H406Y | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67061108; called by muse, mutect2
- RAB3C | c.655C>T p.P219S | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs764132162, COSV51442889; called by muse, mutect2, varscan2
- RNF215 | c.357G>T p.E119D | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.048); catalogued as COSV99306422; called by muse, mutect2
- ROBO2 | c.2479G>A p.E827K | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs571504400, COSV59942096; called by muse, mutect2, varscan2
- SKIV2L | c.2650G>T p.D884Y | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.067); catalogued as COSV61715220; called by muse, mutect2, varscan2
- SORCS3 | c.1397C>A p.T466K | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.949); catalogued as COSV63826429; called by muse, mutect2, varscan2
- SYTL4 | c.519G>C p.Q173H | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT tolerated (0.58); PolyPhen benign (0.332); catalogued as COSV52172260; called by muse, mutect2
- TBC1D9B | c.2146G>A p.G716S | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100783454; called by muse, mutect2, varscan2
- TMEM120A | c.564G>A p.R188= | Splice Region (SNP) | VAF 4/24 reads (17%) | catalogued as rs782743658, COSV100115510; called by muse, mutect2
- TMEM135 | c.637C>T p.H213Y | Missense Mutation (SNP) | VAF 11/122 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.036); catalogued as COSV59707117; called by muse, mutect2
- TRIM22 | c.955G>T p.D319Y | Missense Mutation (SNP) | VAF 13/154 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV66090672, COSV66091936; called by muse, mutect2
- TSNARE1 | c.202G>T p.A68S | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.175); catalogued as COSV56184735; called by muse, mutect2, varscan2
- UROC1 | c.1811G>C p.G604A | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760134412, COSV52039916; called by muse, mutect2, varscan2
- WDR3 | c.1927C>T p.P643S | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.102); catalogued as rs780090748, COSV60469269; called by muse, mutect2, varscan2
- ZBED9 | c.2452A>T p.S818C | Missense Mutation (SNP) | VAF 24/158 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.52); catalogued as COSV71729802; called by muse, mutect2, varscan2
- ZDBF2 | c.1726T>A p.S576T | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV65630528; called by muse, mutect2, varscan2
- ZNF226 | c.1127C>T p.S376F | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.757); catalogued as COSV56197085; called by muse, mutect2, varscan2
- ZNF474 | c.202C>A p.L68I | Missense Mutation (SNP) | VAF 14/202 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.06); catalogued as COSV56947867; called by muse, mutect2
- ZZEF1 | c.2768A>G p.K923R | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1291056581, COSV67560446; called by muse, mutect2
- DMWD | c.1088G>C p.R363P | Missense Mutation (SNP) | VAF 7/128 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DNA2 | c.1958_1976del p.G653Vfs*4 | Frame Shift Del (DEL) | VAF 20/200 reads (10%) | called by mutect2, pindel
- GGNBP2 | c.1450G>T p.D484Y | Missense Mutation (SNP) | VAF 15/174 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2
- HMCN1 | c.13692dup p.G4565Wfs*17 | Frame Shift Ins (INS) | VAF 10/44 reads (23%) | called by mutect2, varscan2
- MKKS | c.156_169del p.Y53Lfs*33 | Frame Shift Del (DEL) | VAF 7/78 reads (9%) | called by mutect2, pindel
- SLC6A14 | c.432T>G p.F144L | Missense Mutation (SNP) | VAF 8/177 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- SPATA31A3 | c.406C>A p.Q136K | Missense Mutation (SNP) | VAF 22/509 reads (4%) | SIFT tolerated (0.51); PolyPhen benign (0.001); called by muse, mutect2
- SUPT20HL1 | c.1793C>A p.A598D | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.057); called by muse, mutect2
- TRBV3-1 | c.336C>G p.S112R | Missense Mutation (SNP) | VAF 7/139 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TRRAP | c.872del p.L291* | Frame Shift Del (DEL) | VAF 10/98 reads (10%) | called by mutect2, pindel
- ABCA6 | c.1302C>T p.F434= | Silent (SNP) | VAF 3/48 reads (6%) | catalogued as COSV52645630; called by muse, mutect2
- ABHD5 | c.396G>A p.V132= | Silent (SNP) | VAF 29/228 reads (13%) | catalogued as rs373148191, COSV50007116; called by muse, mutect2, varscan2
- ALG10 | c.1125A>T p.P375= | Silent (SNP) | VAF 10/75 reads (13%) | catalogued as COSV56794348; called by muse, mutect2, varscan2
- ANK2 | c.8832C>A p.T2944= | Silent (SNP) | VAF 31/237 reads (13%) | catalogued as COSV52191080; called by muse, mutect2, varscan2
- ANXA6 | c.879C>T p.F293= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs781611897, COSV100636816; called by muse, mutect2
- ATP2B4 | c.96C>A p.L32= | Silent (SNP) | VAF 39/262 reads (15%) | catalogued as COSV58175372, COSV58184476; called by muse, mutect2, varscan2
- ATRNL1 | c.759C>T p.C253= | Silent (SNP) | VAF 10/81 reads (12%) | catalogued as rs200296037, COSV61814876; called by muse, mutect2, varscan2
- BEX3 | c.150C>A p.A50= | Silent (SNP) | VAF 18/351 reads (5%) | catalogued as COSV100244237; called by muse, mutect2
- BRINP2 | c.204T>C p.A68= | Silent (SNP) | VAF 12/151 reads (8%) | catalogued as COSV64180577; called by muse, mutect2
- CACNA1S | c.1920C>T p.Y640= | Silent (SNP) | VAF 28/282 reads (10%) | catalogued as COSV62944214; called by muse, varscan2
- CNTN5 | c.2598G>A p.V866= | Silent (SNP) | VAF 8/73 reads (11%) | catalogued as COSV54361132; called by muse, mutect2, varscan2
- COL22A1 | c.4308G>A p.E1436= | Silent (SNP) | VAF 38/114 reads (33%) | catalogued as COSV57347163, COSV57362679; called by muse, mutect2, varscan2
- CSMD2 | c.1825C>T p.L609= | Silent (SNP) | VAF 11/130 reads (8%) | catalogued as rs769998248, COSV53957048; called by muse, mutect2
- CTSG | c.99C>A p.P33= | Silent (SNP) | VAF 36/206 reads (17%) | catalogued as COSV53537038; called by muse, mutect2, varscan2
- DCHS1 | c.1728C>A p.P576= | Silent (SNP) | VAF 5/96 reads (5%) | catalogued as COSV100201653; called by muse, mutect2
- DISP2 | c.2352C>A p.G784= | Silent (SNP) | VAF 17/216 reads (8%) | catalogued as COSV51145547; called by muse, mutect2
- DUSP19 | c.259C>T p.L87= | Silent (SNP) | VAF 7/66 reads (11%) | catalogued as COSV100700210; called by muse, mutect2
- FLVCR2 | c.93C>A p.P31= | Silent (SNP) | VAF 46/222 reads (21%) | catalogued as COSV53163737; called by muse, mutect2, varscan2
- FSCB | c.2295G>T p.V765= | Silent (SNP) | VAF 31/150 reads (21%) | catalogued as COSV100468977; called by muse, mutect2, varscan2
- GRM7 | c.297G>C p.V99= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as COSV63173646; called by muse, mutect2, varscan2
- HTR1D | c.246C>A p.T82= | Silent (SNP) | VAF 12/214 reads (6%) | catalogued as COSV100024725; called by muse, mutect2
- KCNAB1 | c.930G>A p.G310= (on ENST00000490337 / NM_172160.3; = p.G299= on NM_003471.3) | Silent (SNP) | VAF 12/97 reads (12%) | catalogued as COSV100203986; called by muse, mutect2, varscan2
- KPRP | c.36G>T p.P12= | Silent (SNP) | VAF 21/104 reads (20%) | catalogued as rs761781923, COSV64222236, COSV64223096; called by muse, mutect2, varscan2
- LSP1 | c.528C>A p.P176= | Silent (SNP) | VAF 14/263 reads (5%) | catalogued as COSV61137836; called by muse, mutect2
- LUZP2 | c.915A>C p.A305= | Silent (SNP) | VAF 9/140 reads (6%) | catalogued as COSV61219524; called by muse, mutect2
- MMP3 | c.1128C>T p.I376= | Silent (SNP) | VAF 14/75 reads (19%) | catalogued as COSV55408311; called by muse, mutect2, varscan2
- MSI2 | c.378A>C p.V126= | Silent (SNP) | VAF 13/159 reads (8%) | catalogued as COSV52369308; called by muse, mutect2
- OR1J2 | c.486C>A p.L162= | Silent (SNP) | VAF 8/168 reads (5%) | catalogued as COSV58945409; called by muse, mutect2
- OR4M1 | c.453G>T p.G151= | Silent (SNP) | VAF 60/244 reads (25%) | catalogued as COSV60063785; called by muse, mutect2, varscan2
- OR7G1 | c.138C>G p.L46= | Silent (SNP) | VAF 10/162 reads (6%) | catalogued as COSV53319131, COSV99528779; called by muse, mutect2
- PCDHB11 | c.2157G>T p.A719= | Silent (SNP) | VAF 23/314 reads (7%) | catalogued as COSV61314045, COSV61314188; called by muse, mutect2
- PNPLA8 | c.1944A>G p.P648= | Silent (SNP) | VAF 17/135 reads (13%) | catalogued as rs771282623, COSV57555046; called by muse, mutect2, varscan2
- PRAMEF1 | c.405A>G p.A135= | Silent (SNP) | VAF 18/354 reads (5%) | catalogued as COSV60019394; called by muse, mutect2
- PSG7 | c.321G>T p.L107= | Silent (SNP) | VAF 34/880 reads (4%) | catalogued as COSV68446805; called by muse, mutect2
- QPCTL | c.270A>T p.P90= | Silent (SNP) | VAF 10/200 reads (5%) | catalogued as COSV99171222; called by muse, mutect2
- RHAG | c.729G>T p.T243= | Silent (SNP) | VAF 14/157 reads (9%) | catalogued as COSV57706648; called by muse, mutect2
- SAMSN1 | c.633G>T p.V211= | Silent (SNP) | VAF 13/152 reads (9%) | catalogued as COSV53478106; called by muse, mutect2
- TAF9B | c.21G>T p.A7= | Silent (SNP) | VAF 13/245 reads (5%) | catalogued as COSV59372453; called by muse, mutect2
- THOC6 | c.69C>G p.L23= | Silent (SNP) | VAF 7/130 reads (5%) | catalogued as COSV99560455; called by muse, mutect2
- TRBV30 | c.105G>T p.P35= | Silent (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2
- WSCD1 | c.1254T>A p.I418= | Silent (SNP) | VAF 10/75 reads (13%) | catalogued as rs1392012900, COSV58498706; called by muse, mutect2, varscan2
- ZNF79 | c.237T>G p.L79= | Silent (SNP) | VAF 10/201 reads (5%) | catalogued as COSV61071986; called by muse, mutect2
